Gene-level copy-number profile of tumor specimen C3N-03882-01 from CPTAC case C3N-03882, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 68.9 years (25,174 days).
Specimen C3N-03882-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 3f6da40c-061f-433d-9d3e-d6b5ab8c16f9.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03882-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/7cb31790-26a9-49ae-8db4-6e0d26ea5e41

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 631; copy number 1: 1,100; copy number 2: 21,849; copy number 3: 18,658; copy number 4: 10,977; copy number 5: 2,287; copy number 6: 882; copy number 7: 265; copy number 8: 461; copy number 9: 840; copy number 10: 390; copy number 11: 237; copy number 12: 5; copy number 13: 4; copy number 14: 201; copy number 15: 51; copy number 20: 17; copy number 21: 23; copy number 23: 16.

Homozygous deletions (total copy number 0; autosomes only): 129 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:112,466,541–112,700,746, 8 genes (within-gene range 0–2): WNT2B, AL354760.1, ST7L, CAPZA1, MRPL53P1, RNU7-70P, MOV10, AL603832.1.
- chr3:88,948,142–90,261,708, 10 genes: ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr4:68,537,184–68,670,652, 5 genes (within-gene range 0–2): UGT2B17, AC147055.2, AC147055.4, AC147055.3, UGT2B15.
- chr4:78,379,197–78,379,514, 1 gene (within-gene range 0–2): MICOS10P4.
- chr5:181,306,502–181,324,685, 1 gene: AC138035.1.
- chr6:28,503,296–29,978,410, 101 genes (broad region; genes not listed).
- chr8:31,497,423–31,598,204, 2 genes: AC068672.1, RNA5SP261.
- chr12:11,351,823–11,395,566, 1 gene (within-gene range 0–2): PRB1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,678 genes in 36 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,264,372–120,467,739, 49 genes, copy number 10–15: RNA5SP56, PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2.
- chr1:143,419,625–153,460,651, 418 genes, copy number 5 (broad region; genes not listed).
- chr1:158,254,424–159,649,620, 57 genes, copy number 7: CD1A, HMGN1P5, CD1C, CD1B, CD1E, OR10T2, OR10K2, OR10T1P, EI24P2, OR10K1, OR10R2, AL365440.1, OR10R3P, OR10R1P, HSP90AA3P, OR6Y1, OR6P1, OR10X1, OR10Z1, SPTA1, OR6K1P, OR6K2, OR6K3, OR6K4P, OR6K5P, OR6N1, OR6K6, OR6N2, OR2AQ1P, OR10AA1P, MNDA, PYHIN5P, PYHIN1, IFI16, AIM2, RAD1P2, CADM3, RNA5SP60, CADM3-AS1, ACKR1, MPTX1, OR10J2P, FCER1A, OR10J3, AL513323.1, OR10J7P, OR10J8P, OR10J9P, OR10J4, OR10J1, LINC02819, OR10J5, AL606752.1, OR10AE1P, APCS, OR10J6P, AL445528.2.
- chr2:2,707,368–2,840,512, 1 gene, copy number 5 (within-gene range 4–5): AC011995.2.
- chr2:2,870,558–5,314,134, 30 genes, copy number 5: AC011995.1, LINC01250, AC019118.2, AC019118.1, EIPR1, EIPR1-IT1, TRAPPC12, TRAPPC12-AS1, AC114810.1, ADI1, AC231981.1, AC108488.1, AC108488.2, RNASEH1, RNASEH1-AS1, RPS7, COLEC11, AC010907.2, TMSB4XP2, ALLC, GAPDHP48, AC010907.1, DCDC2C, LINC01304, AC012445.1, NPM1P48, LINC01249, AC092169.1, RNU6-649P, AC073143.1.
- chr2:52,722,671–55,419,895, 40 genes, copy number 5: AC010967.1, AC010967.2, AC010967.3, AC069157.2, AC069157.1, ASB3, RNU6-997P, CHAC2, ERLEC1, MIR3682, GPR75, PSME4, ACYP2, RPL21P30, HMGB1P31, AC008280.1, AC008280.2, RNU7-172P, TSPYL6, C2orf73, SPTBN1, SPTBN1-AS1, RPL23AP32, AC092839.1, AC093110.1, EML6, EML6-AS1, AC104781.1, RNU7-81P, RTN4, RNU6-433P, CLHC1, AC012358.1, CDPF1P1, RPS27A, MTIF2, PRORSD1P, AC012358.2, Y_RNA, CCDC88A.
- chr2:62,069,447–88,452,693, 507 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr2:169,790,093–169,790,885, 1 gene, copy number 6: CYB5AP2.
- chr3:149,761,100–149,968,385, 1 gene, copy number 8 (within-gene range 4–8): ANKUB1.
- chr3:149,812,770–198,123,232, 841 genes, copy number 5–23 (within-gene range 5–42) (broad region; genes not listed).
- chr4:46,243,548–49,062,081, 38 genes, copy number 6–10 (within-gene range 4–10): GABRA2, AC095060.1, RNU6-412P, RAC1P2, COX7B2, GABRA4, GABRB1, AC107398.3, COMMD8, AC107398.4, ATP10D, AC107398.1, AC107398.2, CORIN, MIR8053, AC092597.1, AC107068.2, AC107068.1, NFXL1, NIPAL1, CNGA1, TXK, RNU6-838P, U6, TEC, Y_RNA, SLAIN2, SLC10A4, ZAR1, FRYL, RNU5E-3P, OCIAD1, OCIAD1-AS1, OCIAD2, RNU6-158P, AC020593.1, CWH43, TPI1P4.
- chr4:49,486,926–49,524,185, 5 genes, copy number 5: AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8.
- chr4:51,843,000–56,710,614, 100 genes, copy number 7–14 (broad region; genes not listed).
- chr5:8,980,404–8,980,659, 1 gene, copy number 6: AC091895.1.
- chr6:63,392,222–65,707,226, 19 genes, copy number 8: AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr6:66,710,242–67,625,464, 7 genes, copy number 5: AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA.
- chr7:57,270,839–62,275,678, 31 genes, copy number 6–15: AC099654.3, AC237221.2, AC237221.1, MIR3147, VN1R28P, SAPCD2P2, ZNF716, AC092175.1, NCOR1P3, AC064862.6, AC064862.7, BSNDP4, AC064862.1, AC064862.5, AC064862.2, AC064862.4, AC064862.3, AC023141.4, AC023141.8, AC023141.5, AC023141.12, AC023141.2, AC023141.9, AC023141.11, AC023141.3, AC023141.1, AC023141.10, AC023141.6, AC023141.7, AC023141.13, AC128676.1.
- chr8:36,987,977–51,015,165, 245 genes, copy number 5–9 (broad region; genes not listed).
- chr8:51,319,577–128,564,679, 1,113 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr8:135,859,369–145,066,685, 217 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr10:74,506,081–74,530,553, 2 genes, copy number 10 (within-gene range 4–10): AC022540.1, MRPL35P3.
- chr10:74,744,386–80,941,201, 132 genes, copy number 10–14 (broad region; genes not listed).
- chr11:68,891,276–77,301,687, 282 genes, copy number 10 (broad region; genes not listed).
- chr12:21,047,179–21,942,529, 18 genes, copy number 5 (within-gene range 4–5): AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2.
- chr12:84,154,434–86,838,904, 17 genes, copy number 5 (within-gene range 4–5): AC090679.2, AC090679.1, AC087888.1, AC093027.1, SLC6A15, AC128657.1, TSPAN19, LRRIQ1, ALX1, LINC02820, AC126471.1, AC137768.1, RASSF9, NTS, MGAT4C, AC016993.1, AC139697.1.
- chr14:18,333,726–18,945,139, 27 genes, copy number 6–8: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2.
- chr14:19,999,913–22,829,820, 262 genes, copy number 5–14 (broad region; genes not listed).
- chr14:95,319,483–106,879,812, 570 genes, copy number 5–14 (within-gene range 4–14) (broad region; genes not listed).
- chr16:24,236,104–26,358,355, 37 genes, copy number 6: LINC02194, CACNG3, AC004125.1, RNU7-24P, AC008938.1, RBBP6, TNRC6A, LINC01567, AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39, HS3ST4, AC093516.1, AC093524.1, MIR548W, RNA5SP405, HMGN2P3, HSPE1P16, AC009158.1, AC130464.1.
- chr16:46,469,341–46,844,618, 16 genes, copy number 5: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1.
- chr17:50,055,968–50,562,108, 36 genes, copy number 5–6 (within-gene range 4–6): ITGA3, AC002401.4, PDK2, AC002401.3, AC002401.2, SAMD14, PPP1R9B, AC002401.1, AC015909.2, AC015909.3, SGCA, H1-9P, COL1A1, AC015909.1, AC015909.4, SUMO2P7, TMEM92, TMEM92-AS1, XYLT2, AC015909.5, MRPL27, EME1, LRRC59, Y_RNA, AC004707.1, ACSF2, MRPS21P9, CHAD, AC021491.4, RSAD1, AC021491.1, MYCBPAP, AC021491.2, EPN3, SPATA20, CACNA1G-AS1.
- chr18:20,946,906–33,441,101, 200 genes, copy number 5–7 (broad region; genes not listed).
- chr19:27,638,483–38,208,369, 344 genes, copy number 5–9 (broad region; genes not listed).
- chr21:9,975,017–10,516,431, 9 genes, copy number 5 (within-gene range 3–5): CR382285.1, CR382285.2, CR382287.1, CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2.
- chr21:12,999,676–13,067,033, 3 genes, copy number 6: AP001464.1, ANKRD30BP2, RNU6-614P.
- chr22:18,361,820–18,391,105, 2 genes, copy number 6: FAM230J, AC011718.1.

Autosomal genes at a single copy (total copy number 1): 1,091. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
